Gene-level copy-number profile of tumor specimen C3L-08561-01 from CPTAC case C3L-08561, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 82.9 years (30,276 days).
Specimen C3L-08561-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd32ef3b-4894-45ea-b890-d8442772f58c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08561-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/6c14e722-e630-41de-92af-484fb49a42e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 161; copy number 1: 298; copy number 2: 58,363; copy number 3: 53; copy number 4: 26; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 156 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 2 genes (within-gene range 0–2): AL627309.1, AL627309.3.
- chr1:196,819,731–196,959,622, 4 genes (within-gene range 0–2): CFHR1, BX248415.1, CFHR4, CFHR2.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr4:184,387,729–184,694,963, 9 genes (within-gene range 0–2): IRF2, SNORD79, AC099343.2, IRF2-DT, LINC02427, AC099343.1, LINC02365, CASP3, PRIMPOL.
- chr5:135,648,584–135,653,935, 1 gene: SLC25A48-AS1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:46,337,224–46,358,714, 1 gene: AGAP14P.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr13:94,436,811–99,200,757, 74 genes (broad region; genes not listed).
- chr13:99,205,708–99,215,758, 2 genes (within-gene range 0–2): RN7SKP9, H2AZP3.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–2): ACOT1, NT5CP2.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr15:20,916,686–20,940,333, 2 genes: NF1P1, MIR5701-1.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–2): RNU6-1159P, RNU6-115P.
- chr21:41,141,493–42,055,130, 27 genes: LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1.
- chr22:18,873,543–18,894,407, 2 genes: FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:71,125,085–71,586,310, 3 genes, copy number 6 (within-gene range 2–6): TSPAN8, LGR5, AC090116.1.

Autosomal genes at a single copy (total copy number 1): 298. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
